Somatic mutation profile of tumor specimen TCGA-QR-A708-01A (aliquot TCGA-QR-A708-01A-11D-A35D-08) from TCGA case TCGA-QR-A708, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Pheochromocytoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 44.3 years (16,170 days).
Specimen TCGA-QR-A708-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cba58d37-6791-4464-a98e-e129557f902f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-QR-A708-10A (Blood Derived Normal), aliquot TCGA-QR-A708-10A-01D-A35B-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2e8bec72-93ef-4239-af6a-130fb2ee7144

The open-access MAF lists 18 somatic variants for this specimen: 15 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Frame Shift Del 2, Silent 2, 3'UTR 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRTAP4-2 | c.379C>T p.R127C | Missense Mutation (SNP) | VAF 43/141 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs367648183; called by muse, mutect2, varscan2
- LAMB2 | c.4143C>A p.S1381R | Missense Mutation (SNP) | VAF 44/74 reads (59%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1389882594; called by muse, mutect2
- OR6Y1 | c.757G>A p.V253I | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs778416815, COSV56928801; called by muse, mutect2, varscan2
- OSBPL7 | c.821C>G p.P274R | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV99137095; called by muse, mutect2, varscan2
- TTN | c.49244G>A p.R16415Q (on ENST00000591111; = p.R8991Q on NM_003319.4) | Missense Mutation (SNP) | VAF 87/217 reads (40%) | PolyPhen benign (0.131); catalogued as rs376932266, COSV59983027; ClinVar: uncertain significance; called by muse, varscan2
- A2M | c.1232C>G p.T411S | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CGGBP1 | c.454C>A p.P152T | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); called by muse, mutect2
- CST5 | c.62G>T p.G21V | Missense Mutation (SNP) | VAF 29/90 reads (32%) | SIFT tolerated (0.54); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- LAMB2 | c.4141A>T p.S1381C | Missense Mutation (SNP) | VAF 44/74 reads (59%) | SIFT deleterious (0); PolyPhen benign (0.145); called by muse, mutect2
- OR9G4 | c.57del p.D20Ifs*13 | Frame Shift Del (DEL) | VAF 7/70 reads (10%) | called by mutect2, pindel, varscan2
- PHLDB2 | c.314T>C p.M105T | Missense Mutation (SNP) | VAF 158/290 reads (54%) | SIFT tolerated, low confidence (0.85); PolyPhen benign (0); called by muse, mutect2, varscan2
- PPIG | c.1177_1181del p.E393Sfs*6 | Frame Shift Del (DEL) | VAF 27/90 reads (30%) | called by mutect2, pindel, varscan2
- SLC25A23 | c.503G>T p.C168F | Missense Mutation (SNP) | VAF 26/95 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- SUPT20HL1 | c.7C>T p.R3* | Nonsense Mutation (SNP) | VAF 17/65 reads (26%) | called by muse, mutect2
- VCP | c.1499C>T p.P500L | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- TELO2 | c.1329C>G p.P443= | Silent (SNP) | VAF 10/17 reads (59%) | catalogued as rs541069927; called by muse, mutect2, varscan2
- TOGARAM1 | c.4299A>G p.P1433= | Silent (SNP) | VAF 20/83 reads (24%) | catalogued as rs749336651; called by muse, mutect2, varscan2
- ZNF99 | c.*37G>T | 3'UTR (SNP) | VAF 20/89 reads (22%) | called by muse, mutect2, varscan2
